Somatic mutation profile of tumor specimen TCGA-S9-A7J0-01A (aliquot TCGA-S9-A7J0-01A-11D-A34A-08) from TCGA case TCGA-S9-A7J0, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.1 years (10,989 days).
Specimen TCGA-S9-A7J0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15d6af6e-5930-48d2-8856-7ab8c69b34d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7J0-10A (Blood Derived Normal), aliquot TCGA-S9-A7J0-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48c7ba2b-3821-4c69-a25f-fbce494aff0e

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 27, Silent 11, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 70/120 reads (58%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 62/145 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 78/85 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99327348; called by muse, mutect2, varscan2
- AUTS2 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100714950; called by muse, mutect2, varscan2
- CDCP1 | c.2345G>C p.R782T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs1303558006, COSV99943825; called by muse, mutect2, varscan2
- CDH17 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as rs1040211278, COSV50329695, COSV99218041; called by muse, mutect2, varscan2
- CRHR2 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs772634618, COSV100529921, COSV59264393, COSV59268177; called by muse, mutect2, varscan2
- CYP51A1 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as COSV50151554; called by muse, mutect2, varscan2
- EVC2 | c.3746T>C p.I1249T | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs200968626, COSV100185000; called by muse, mutect2, varscan2
- FAT2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV55814177; called by muse, mutect2, varscan2
- FKBP10 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs782511568, COSV58637928; called by muse, mutect2, varscan2
- IL5RA | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99842639; called by muse, mutect2, varscan2
- KIF2B | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs762901378, COSV52128005; called by muse, mutect2, varscan2
- LRRC66 | c.1205A>T p.D402V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100602823; called by muse, mutect2, varscan2
- MDC1 | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV64526354; called by muse, mutect2, varscan2
- MGAT1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV100286505; called by muse, mutect2, varscan2
- MIDEAS | c.2783G>T p.R928M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV99678554; called by muse, mutect2, varscan2
- MRGPRX1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs567589026, COSV57107622; called by muse, mutect2, varscan2
- MYH6 | c.4307G>A p.R1436H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs142556730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTX1 | c.945C>G p.D315E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV56995070, COSV99246140; called by muse, mutect2, varscan2
- PANX3 | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99421169; called by muse, mutect2, varscan2
- PCDHA8 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65327302; called by muse, mutect2, varscan2
- PDE4B | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as COSV100302158; called by muse, mutect2, varscan2
- PTK6 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); catalogued as rs1405570524, COSV99420264; called by muse, mutect2, varscan2
- SLC8A2 | c.1885+1G>A p.X629_splice | Splice Site (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99369635; called by muse, mutect2, varscan2
- SUGP1 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs772549956; called by muse, mutect2
- SYCE1 | c.625G>A p.V209M (on ENST00000343131 / NM_001143764.3; = p.V173M on NM_130784.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs746219658, COSV100385637; called by muse, mutect2, varscan2
- TAAR2 | c.784A>T p.K262* (on ENST00000367931 / NM_001033080.1; = p.K217* on NM_014626.3) | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99255524; called by muse, mutect2, varscan2
- USP54 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1218641127, COSV100160897; called by muse, mutect2, varscan2
- ATRX | c.2656_2659del p.E886Lfs*18 | Frame Shift Del (DEL) | VAF 160/354 reads (45%) | called by mutect2, varscan2
- CTNND2 | c.412del p.D138Tfs*194 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | called by mutect2, pindel, varscan2
- PREP | c.824T>C p.I275T (on ENST00000369110; = p.I341T on NM_002726.5) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- RECK | c.1063_1066del p.Y355Vfs*24 | Frame Shift Del (DEL) | VAF 42/121 reads (35%) | called by pindel, varscan2
- ARHGAP6 | c.2673G>A p.A891= (on ENST00000337414 / NM_013427.3; = p.A688= on NM_013423.3) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1285310327, COSV100272238; called by muse, mutect2, varscan2
- BRINP1 | c.2016A>G p.A672= | Silent (SNP) | VAF 58/157 reads (37%) | catalogued as COSV99774376; called by muse, mutect2, varscan2
- CACNA1G | c.7014C>T p.S2338= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs367861396, COSV61738682; called by muse, mutect2
- CD1D | c.273T>C p.Y91= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV100939536; called by muse, mutect2, varscan2
- EP400 | c.8838C>T p.P2946= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100200371; called by muse, mutect2, varscan2
- GLIS3 | c.867C>A p.P289= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as rs754101625, COSV60925754; called by muse, mutect2, varscan2
- PARD6B | c.681C>T p.S227= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as rs746295892, COSV100859859; called by muse, mutect2, varscan2
- PCARE | c.1251T>C p.A417= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs765199610, COSV100527292; called by muse, mutect2, varscan2
- PRRC2A | c.5646C>T p.P1882= | Silent (SNP) | VAF 87/165 reads (53%) | catalogued as rs749739603, COSV99276414; called by muse, mutect2, varscan2
- SLC26A4 | c.339C>T p.V113= | Silent (SNP) | VAF 109/187 reads (58%) | catalogued as rs780236833, COSV99706528; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC4A9 | c.435C>T p.C145= (on ENST00000507527 / NM_001258428.2; = p.C121= on NM_031467.3) | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV99138394; called by muse, mutect2, varscan2
